Gene-level copy-number profile of tumor specimen TCGA-L5-A88V-01A from TCGA case TCGA-L5-A88V, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: GX; Age at diagnosis: 60.4 years (22,066 days).
Specimen TCGA-L5-A88V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.b27f6586-b749-4dde-a245-2f1dbf3e8646.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A88V-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3295c2fb-f376-48a0-9fa4-9a817914c763

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 627; copy number 2: 18,008; copy number 3: 17,147; copy number 4: 20,364; copy number 5: 1,559; copy number 6: 1,131; copy number 7: 375; copy number 8: 69; copy number 9: 172; copy number 10: 64; copy number 11: 1; copy number 12: 106; copy number 13: 4; copy number 14: 91; copy number 15: 32; copy number 16: 8; copy number 24: 13; copy number 52: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A88V-01A-11D-A350-01): tumor purity 0.77, ploidy 3.3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr4:37,454,698–37,476,401, 1 gene: AC022463.1.
- chr4:90,370,123–90,370,427, 1 gene: RN7SKP248.
- chr8:22,895,434–22,897,813, 1 gene: AC037441.2.
- chr12:98,931,682–98,976,656, 1 gene (within-gene range 0–2): AC069437.1.
- chr16:78,550,739–78,553,296, 1 gene: AC046158.3.
- chr22:16,572,027–16,837,666, 19 genes: AP000547.1, KCNMB3P1, CCT8L2, AP000547.4, FABP5P11, TPTEP1, AP000547.3, AP000365.1, SLC25A15P5, PARP4P3, ANKRD62P1-PARP4P3, ANKRD62P1, AC005301.1, VWFP1, AC005301.2, LINC01665, XKR3, HSFY1P1, GPM6BP3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 506 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:113,376,669–113,616,958, 4 genes, copy number 9–11: AC107890.1, AC055788.2, AC055788.1, AC103993.1.
- chr8:119,730,774–128,187,101, 145 genes, copy number 10–16 (within-gene range 3–16) (broad region; genes not listed).
- chr8:128,634,199–131,040,909, 28 genes, copy number 13–15 (within-gene range 3–15): CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, AC103718.1, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1, ADCY8, AC103726.1, AC103726.2.
- chr9:68,328,308–68,531,061, 1 gene, copy number 9 (within-gene range 5–9): PGM5.
- chr9:68,426,843–73,649,839, 69 genes, copy number 9–10 (broad region; genes not listed).
- chr9:119,495,375–119,524,125, 1 gene, copy number 9: AC006288.1.
- chr11:67,583,742–67,723,455, 13 genes, copy number 12: GSTP1, C11orf72, AP003385.3, NDUFV1, DOC2GP, NUDT8, TBX10, ACY3, AP003385.1, ALDH3B2, RPL37P2, UNC93B5, OR7E145P.
- chr11:68,980,021–69,367,726, 13 genes, copy number 24 (within-gene range 4–24): MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P.
- chr11:69,475,567–69,819,416, 8 genes, copy number 15: LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3.
- chr13:28,495,633–35,673,022, 106 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr17:38,702,262–38,853,764, 20 genes, copy number 14: MIR4734, AC006449.6, AC006449.2, MLLT6, AC006449.3, MIR4726, AC006449.7, CISD3, RNA5SP440, PCGF2, AC006449.5, PSMB3, RNU6-866P, PIP4K2B, CWC25, MIR4727, C17orf98, RPL23, SNORA21B, SNORA21.
- chr17:39,404,285–39,747,291, 15 genes, copy number 52 (within-gene range 7–52): MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7.
- chr19:14,927,052–16,472,085, 83 genes, copy number 12 (within-gene range 2–12) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 627. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
